Somatic mutation profile of tumor specimen TCGA-18-3416-01A (aliquot TCGA-18-3416-01A-01D-0983-08) from TCGA case TCGA-18-3416, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 83.3 years (30,435 days).
Specimen TCGA-18-3416-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6547c701-fa8a-4593-a152-210e38ed5a15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-3416-11A (Solid Tissue Normal), aliquot TCGA-18-3416-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17cc5400-1a3c-42bf-995b-60a5d8684787

The open-access MAF lists 321 somatic variants for this specimen: 242 protein-altering or splice-affecting, 67 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 202, Silent 67, Nonsense Mutation 20, Frame Shift Del 7, Splice Site 6, Splice Region 5, Intron 4, RNA 3, 3'UTR 2, 3'Flank 2, Frame Shift Ins 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN5A | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs199473071, CM064255, CM147665, COSV61120607, COSV61125758; ClinVar: not provided / likely pathogenic / uncertain significance; called by muse, mutect2
- AATK | c.2879C>A p.P960H (on ENST00000326724 / NM_001080395.3; = p.P857H on NM_004920.2) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV58365392; called by mutect2, varscan2
- ABCA1 | c.6181G>A p.G2061S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751548064, COSV66065182; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC2 | c.3791C>T p.T1264I | Missense Mutation (SNP) | VAF 126/352 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV64985468; called by muse, mutect2, varscan2
- ABI3BP | c.1369A>T p.T457S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.112); catalogued as COSV52532765; called by muse, mutect2, varscan2
- ADGRE1 | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV51672989, COSV51674141; called by muse, mutect2, varscan2
- AGFG2 | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | catalogued as COSV53544621; called by muse, mutect2, varscan2
- AHSG | c.1018C>A p.R340S | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.065); catalogued as COSV56607413, COSV56608288; called by muse, mutect2, varscan2
- AL592490.1 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV69425533; called by muse, mutect2, varscan2
- ALPK3 | c.2769C>G p.H923Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.676); catalogued as COSV51931933; called by muse, mutect2, varscan2
- ANKRD17 | c.4853G>C p.R1618T | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as COSV58218248; called by muse, mutect2, varscan2
- ANO4 | c.1738G>T p.E580* (on ENST00000392977 / NM_001286615.2; = p.E545* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV54591380, COSV54604896; called by mutect2, varscan2
- ANXA2 | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100221916; called by mutect2, varscan2
- AOPEP | c.2357G>T p.S786I (on ENST00000375315 / NM_001193329.1; = p.S687I on NM_032823.5) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV52988383; called by muse, mutect2, varscan2
- APOB | c.6863A>T p.H2288L | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV51930711, COSV51957470; called by muse, mutect2, varscan2
- ASB2 | c.395C>G p.T132R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV60111246, COSV60113216; called by muse, mutect2, varscan2
- ATM | c.5612C>T p.T1871I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs538452060, COSV53736082; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10A | c.3919G>T p.A1307S | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV63515703; called by muse, mutect2, varscan2
- ATP1A2 | c.2885C>A p.A962D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV63403161; called by muse, mutect2, varscan2
- ATP8B4 | c.3472G>A p.G1158R | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as rs1158773155, COSV52712787; called by muse, mutect2, varscan2
- ATXN7 | c.1244A>T p.H415L | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV55749462; called by muse, mutect2, varscan2
- BMP5 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as rs751770025, COSV63702268; called by muse, mutect2, varscan2
- C2orf80 | c.227G>T p.R76I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100378420, COSV58016240; called by muse, mutect2, varscan2
- C6 | c.1260C>A p.C420* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV54708181; called by muse, mutect2, varscan2
- C8A | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs201034819, COSV63483573; called by mutect2, varscan2
- CACNA1A | c.3193C>G p.L1065V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.212); catalogued as COSV100803357, COSV64194524; called by muse, mutect2, varscan2
- CACNA1G | c.7099G>A p.G2367S | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.028); catalogued as rs772947233, COSV61723494; called by muse, mutect2, varscan2
- CAPN3 | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV55515300; called by muse, mutect2, varscan2
- CARD6 | c.1204C>A p.Q402K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV54564359; called by muse, mutect2, varscan2
- CC2D1B | c.2063A>C p.Q688P | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.696); catalogued as rs1196073998, COSV52559663; called by muse, varscan2
- CCDC141 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 65/111 reads (59%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV55371543; called by muse, mutect2, varscan2
- CCDC185 | c.1488G>T p.E496D | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV64820586; called by muse, mutect2, varscan2
- CDS1 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.076); catalogued as COSV55687144, COSV55687463; called by muse, mutect2, varscan2
- CEP126 | c.385A>T p.R129W | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54823708; called by muse, mutect2, varscan2
- CFAP251 | c.3218G>C p.R1073T | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV56609406; called by muse, mutect2, varscan2
- CFAP58 | c.1840G>C p.G614R | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV63833538; called by muse, mutect2, varscan2
- CFAP61 | c.2957G>A p.R986K | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV55624591; called by muse, mutect2, varscan2
- CFHR5 | c.1066C>A p.R356S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV104375906, COSV56820416; called by muse, mutect2
- CHP1 | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV58156769, COSV58156987, COSV58158535; called by muse, mutect2, varscan2
- CKAP2L | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV56696088; called by muse, varscan2
- CKMT2 | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 46/95 reads (48%) | catalogued as rs375003065; called by muse, varscan2
- CNTN1 | c.1110G>T p.A370= | Splice Region (SNP) | VAF 19/91 reads (21%) | catalogued as COSV100751050; called by muse, mutect2, varscan2
- COL16A1 | c.3035G>T p.G1012V | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV54703549; called by mutect2, varscan2
- COL19A1 | c.3075G>T p.E1025D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV59569696, COSV59577850; called by muse, mutect2, varscan2
- COL6A3 | c.2498-1G>A p.X833_splice | Splice Site (SNP) | VAF 31/60 reads (52%) | catalogued as COSV55085277; called by muse, mutect2, varscan2
- COPS5 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63474290; called by muse, mutect2, varscan2
- CPZ | c.1172A>T p.D391V (on ENST00000360986 / NM_001014447.3; = p.D380V on NM_003652.3) | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59922387; called by muse, mutect2, varscan2
- CSTL1 | c.310C>G p.Q104E | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.973); catalogued as COSV55677950; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54743917, COSV54746442; called by muse, varscan2
- CWH43 | c.1538T>A p.V513E | Missense Mutation (SNP) | VAF 103/191 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV56937701; called by muse, mutect2, varscan2
- DAAM2 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51307265; called by muse, mutect2, varscan2
- DCAF12L1 | c.1294T>A p.Y432N | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64421486; called by muse, mutect2, varscan2
- DCAF8L1 | c.931G>T p.V311L | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV71595204; called by muse, mutect2, varscan2
- DCHS1 | c.4646C>T p.P1549L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV55033544; called by muse, mutect2, varscan2
- DDX1 | c.2093-2A>T p.X698_splice | Splice Site (SNP) | VAF 97/197 reads (49%) | catalogued as COSV51839081; called by muse, mutect2, varscan2
- DICER1 | c.3607A>T p.N1203Y | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.081); catalogued as COSV58617714; called by muse, mutect2, varscan2
- DISP3 | c.2839G>C p.G947R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV53824624; called by mutect2, varscan2
- DNMT3A | c.1455G>C p.Q485H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV53046393; called by muse, mutect2, varscan2
- DOCK8 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 69/104 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs766282048, COSV66633704; called by muse, mutect2, varscan2
- DPH5 | c.510G>T p.Q170H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV59859255; called by muse, mutect2, varscan2
- DST | c.13555C>G p.Q4519E (on ENST00000361203 / NM_001374722.1; = p.Q2107E on NM_015548.5) | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.835); catalogued as rs776042660, COSV55006976; called by muse, mutect2, varscan2
- DST | c.11461G>T p.G3821* (on ENST00000361203 / NM_001374722.1; = p.G1409* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 36/75 reads (48%) | catalogued as COSV55006994; called by muse, mutect2, varscan2
- DTD1 | c.176G>T p.S59I | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV66278772, COSV66279472; called by muse, mutect2, varscan2
- DUSP16 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53807099; called by muse, mutect2, varscan2
- ELAVL1 | c.276+1G>T p.X92_splice | Splice Site (SNP) | VAF 17/37 reads (46%) | catalogued as COSV60966132, COSV60969019; called by muse, mutect2, varscan2
- ENPEP | c.2442A>T p.Q814H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54449010; called by muse, mutect2, varscan2
- EPHB2 | c.2620G>A p.G874S (on ENST00000400191 / NM_001309193.2; = p.G875S on NM_004442.7) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs774876763, COSV65861411; called by muse, mutect2, varscan2
- EPS15L1 | c.1799C>G p.P600R | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as COSV50167910; called by muse, mutect2, varscan2
- ERICH3 | c.1704T>G p.S568R | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV58603446; called by muse, mutect2, varscan2
- ERICH3 | c.430A>T p.S144C | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV58603468; called by muse, mutect2
- EVI5 | c.1969A>G p.S657G | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as COSV64826266; called by muse, mutect2, varscan2
- FAF1 | c.1525A>G p.R509G | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.63); catalogued as COSV65637573; called by muse, mutect2, varscan2
- FAM24A | c.29A>G p.K10R | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as COSV64405867; called by muse, mutect2, varscan2
- FAM47B | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs771339426, COSV61452324; called by muse, mutect2, varscan2
- FAT4 | c.12667C>T p.Q4223* | Nonsense Mutation (SNP) | VAF 20/91 reads (22%) | catalogued as COSV58678683, COSV58693812; called by muse, mutect2, varscan2
- FBN3 | c.5929C>T p.P1977S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54457431; called by muse, mutect2, varscan2
- FLRT1 | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs779400742, COSV55358859; called by mutect2, varscan2
- FLT1 | c.678C>G p.T226= | Splice Region (SNP) | VAF 26/68 reads (38%) | catalogued as COSV56724114; called by muse, varscan2
- FRG2B | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as COSV71042827; called by mutect2, varscan2
- FRMD6 | c.421C>G p.L141V (on ENST00000344768 / NM_001267046.2; = p.L133V on NM_152330.4) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV61087295; called by muse, mutect2, varscan2
- FSCB | c.1039C>A p.L347M | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.366); catalogued as COSV61217452; called by muse, mutect2, varscan2
- FSIP1 | c.1237G>T p.D413Y | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV63224131; called by muse, mutect2, varscan2
- GBP7 | c.319-2A>T p.X107_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99642914; called by muse, varscan2
- GLE1 | c.1008G>C p.K336N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV59407226; called by muse, mutect2, varscan2
- GRAMD1B | c.285T>A p.N95K | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV59202501; called by muse, mutect2, varscan2
- GSG1L | c.898+1G>A p.X300_splice (on ENST00000447459 / NM_001109763.2; = p.X145_splice on NM_144675.2) | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as rs755895622, COSV66575677, COSV99062640; called by mutect2, varscan2
- GSN | c.1414G>T p.D472Y | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57996568; called by muse, mutect2, varscan2
- HEMGN | c.789A>T p.K263N | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV52325899; called by muse, mutect2, varscan2
- HERC4 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as COSV53269791; called by muse, mutect2, varscan2
- HK3 | c.448T>A p.F150I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52838541; called by muse, mutect2, varscan2
- HS6ST3 | c.1340A>T p.H447L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV65005861; called by muse, mutect2, varscan2
- HUNK | c.2019G>T p.R673S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV54226617; called by mutect2, varscan2
- IL9R | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54898967; called by muse, mutect2, varscan2
- INPP4B | c.2576C>G p.S859* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV53718762; called by muse, mutect2, varscan2
- KCNIP4 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV62848061; called by muse, mutect2, varscan2
- KCNQ3 | c.1671G>C p.M557I | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV66467569; called by muse, mutect2, varscan2
- KDM5B | c.4130C>A p.A1377D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52506467; called by muse, mutect2, varscan2
- KIAA1109 | c.1396A>T p.S466C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52667861; called by muse, mutect2, varscan2
- KLF5 | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV66614031; called by muse, mutect2, varscan2
- KLK6 | c.182C>G p.A61G | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59565338, COSV59565742; called by muse, mutect2, varscan2
- KMT2D | c.3958G>T p.G1320* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as CM119938, COSV56426387; called by muse, mutect2, varscan2
- KRTAP3-1 | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1198716277, COSV66957451, COSV66957476; called by mutect2, varscan2
- KRTAP4-5 | c.438C>A p.C146* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV58351982, COSV58353833; called by muse, mutect2, varscan2
- KYAT3 | c.1050A>T p.R350S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53099963; called by mutect2, varscan2
- LCE2D | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs781026851, COSV64228922; called by muse, mutect2, varscan2
- LONRF3 | c.939A>T p.A313= | Splice Region (SNP) | VAF 44/70 reads (63%) | catalogued as COSV59151301; called by muse, mutect2, varscan2
- LRIT1 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.52); PolyPhen benign (0.058); catalogued as rs772075587, COSV64512250; called by mutect2, varscan2
- LRRC17 | c.1276A>G p.R426G | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as COSV50864400; called by muse, mutect2, varscan2
- LRRC55 | c.729G>T p.E243D | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV73006419; called by muse, mutect2, varscan2
- LRRK2 | c.3215C>A p.P1072H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV54149130; called by mutect2, varscan2
- LRRN3 | c.2075C>G p.T692R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.307); catalogued as COSV57818393; called by muse, mutect2, varscan2
- MAEL | c.515A>T p.Q172L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63304723; called by muse, mutect2, varscan2
- MAP7D1 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.254); catalogued as COSV60215716; called by mutect2, varscan2
- MEI1 | c.2609T>G p.L870R | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55902056; called by muse, mutect2, varscan2
- MEMO1 | c.217A>T p.R73* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as COSV54450988; called by mutect2, varscan2
- MFSD1 | c.1333C>A p.Q445K | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV99963666; called by muse, mutect2, varscan2
- MKI67 | c.2665G>A p.V889M | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV64073670; called by muse, mutect2, varscan2
- MPO | c.1730T>A p.M577K | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV51857916; called by muse, varscan2
- MTF2 | c.1533G>T p.Q511H | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs753754787, COSV64770089; called by mutect2, varscan2
- MUC16 | c.2746C>G p.L916V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as COSV67456982; called by muse, mutect2, varscan2
- MUC17 | c.2791G>C p.D931H | Missense Mutation (SNP) | VAF 116/364 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs1332509744, COSV60283487, COSV60284853; called by muse, varscan2
- MYOM1 | c.209A>T p.Q70L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.015); catalogued as COSV55288768; called by muse, mutect2, varscan2
- NCKIPSD | c.1356C>A p.H452Q | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.239); catalogued as COSV53660526; called by muse, mutect2, varscan2
- NECTIN4 | c.1485G>T p.K495N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63512342; called by muse, mutect2, varscan2
- NEIL1 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1386517098, COSV51227470; called by muse, varscan2
- NIBAN2 | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.594); catalogued as COSV64824164; called by muse, mutect2, varscan2
- NOD2 | c.869A>T p.D290V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as COSV56049503; called by muse, mutect2, varscan2
- NOL12 | c.364G>T p.G122W | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs752018030, COSV100767195, COSV63030897; called by muse, mutect2, varscan2
- NPY2R | c.359C>G p.P120R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.029); catalogued as COSV61527765, COSV61529651; called by muse, varscan2
- NUDT9 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV56196384; called by mutect2, varscan2
- OBSCN | c.9152A>G p.N3051S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs371786265; called by muse, mutect2, varscan2
- OR13C8 | c.504C>G p.F168L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.914); catalogued as rs776569089, COSV100623045, COSV58610845; called by muse, mutect2, varscan2
- OR2W3 | c.423C>A p.C141* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as COSV64456220, COSV64456361, COSV64456545; called by muse, mutect2, varscan2
- OR4N2 | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.036); catalogued as COSV60050764; called by muse, mutect2, varscan2
- OR4S2 | c.78T>G p.F26L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV100412754, COSV56746441; called by muse, mutect2, varscan2
- OR4X1 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); catalogued as COSV60722567; called by muse, mutect2, varscan2
- OR51G2 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58992424, COSV58992568; called by muse, mutect2, varscan2
- OR6C65 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV65568338; called by muse, mutect2, varscan2
- OR8G5 | c.764C>A p.A255E | Missense Mutation (SNP) | VAF 63/102 reads (62%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.118); catalogued as COSV100422268; called by muse, mutect2, varscan2
- P2RX3 | c.980C>A p.A327E | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54441971; called by muse, mutect2, varscan2
- P2RX7 | c.1153A>T p.R385W | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV55854408; called by muse, mutect2, varscan2
- P4HA3 | c.1624C>A p.P542T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV59041425; called by muse, mutect2, varscan2
- PARP1 | c.2155-1G>T p.X719_splice | Splice Site (SNP) | VAF 25/59 reads (42%) | catalogued as COSV64689852; called by muse, mutect2, varscan2
- PCDH11Y | c.8G>T p.R3M | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV53078393; called by mutect2, varscan2
- PCDH8 | c.2887C>T p.R963C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1328716563, COSV58811707; called by muse, mutect2, varscan2
- PCDHB12 | c.2151C>A p.S717R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as COSV53394963; called by muse, varscan2
- PDE11A | c.1886G>T p.R629L | Missense Mutation (SNP) | VAF 74/117 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV53691028, COSV53699752; called by muse, mutect2, varscan2
- PDE4B | c.35C>G p.A12G | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.225); catalogued as COSV58472660; called by muse, mutect2, varscan2
- PDZD8 | c.3059G>T p.G1020V | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53689558; called by muse, mutect2, varscan2
- PIGG | c.900C>T p.P300= | Splice Region (SNP) | VAF 31/42 reads (74%) | catalogued as rs1343365553, COSV56317314; called by muse, mutect2, varscan2
- PLCB3 | c.1553G>T p.G518V | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54187330; called by muse, mutect2, varscan2
- PLCE1 | c.2452A>G p.N818D | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.155); catalogued as COSV53344854; called by muse, mutect2, varscan2
- PLCXD3 | c.305A>T p.K102M | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60603933, COSV60607243; called by muse, mutect2, varscan2
- PLEKHG7 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV60821463; called by muse, mutect2, varscan2
- PNLIP | c.926C>A p.T309N | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV65040102; called by muse, mutect2, varscan2
- PPARGC1A | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53526263; called by muse, mutect2, varscan2
- PPP1R3A | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as rs772734887, COSV52879797, COSV52889991; called by muse, mutect2, varscan2
- PRC1 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 38/110 reads (35%) | catalogued as COSV62694889; called by muse, varscan2
- PRMT6 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.056); catalogued as COSV63655269; called by muse, varscan2
- PRUNE2 | c.8564C>G p.T2855R | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV56315472; called by muse, mutect2, varscan2
- PSEN2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); catalogued as COSV60915509; called by muse, mutect2
- PTH2R | c.1621G>T p.G541* | Nonsense Mutation (SNP) | VAF 21/96 reads (22%) | catalogued as COSV55915143, COSV55921068; called by muse, mutect2, varscan2
- PTPRJ | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV69251170; called by muse, mutect2, varscan2
- PXDNL | c.4129A>G p.T1377A | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV62484534; called by muse, mutect2, varscan2
- RAB15 | c.403C>A p.Q135K (on ENST00000533601 / NM_001308154.2; = p.S178R on NM_198686.3) | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.15); catalogued as COSV50824448; called by muse, mutect2, varscan2
- RAF1 | c.1192C>A p.R398S | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52576801; called by muse, mutect2, varscan2
- RANBP6 | c.1589C>T p.T530I | Missense Mutation (SNP) | VAF 58/87 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs779314498, COSV52388819; called by muse, mutect2, varscan2
- RELN | c.6754C>G p.L2252V | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV58994707; called by muse, varscan2
- RELN | c.5110C>T p.P1704S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV58994722, COSV59010972; called by muse, mutect2, varscan2
- RELN | c.3998T>C p.L1333P | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58994731; called by muse, mutect2, varscan2
- RFX3 | c.1212T>G p.S404R | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT tolerated (0.3); PolyPhen benign (0.196); catalogued as COSV56512565; called by muse, mutect2, varscan2
- RFX4 | c.889G>A p.A297T (on ENST00000392842 / NM_213594.3; = p.A203T on NM_032491.6) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57574467; called by muse, mutect2, varscan2
- RIMS2 | c.1199G>T p.R400L (on ENST00000666250 / NM_001348490.2; = p.R208L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as COSV51669256, COSV51723221; called by muse, mutect2, varscan2
- RNASE4 | c.294C>A p.N98K | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59011837; called by muse, varscan2
- RNF157 | c.139A>T p.T47S | Missense Mutation (SNP) | VAF 58/82 reads (71%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs780293331, COSV99486694; called by muse, varscan2
- SALL4 | c.925G>T p.G309W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53851240; called by mutect2, varscan2
- SAMD9L | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV59080603; called by muse, mutect2, varscan2
- SCAP | c.1038C>A p.G346= | Splice Region (SNP) | VAF 7/17 reads (41%) | catalogued as COSV55560341; called by muse, mutect2, varscan2
- SDK1 | c.3950G>T p.R1317L | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV67363048; called by muse, mutect2, varscan2
- SESN3 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV53584155; called by muse, mutect2, varscan2
- SETX | c.4536G>T p.M1512I | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV56382424; called by muse, mutect2, varscan2
- SFTPA2 | c.362C>A p.T121K | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV64882365; called by muse, mutect2, varscan2
- SGPL1 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.347); catalogued as COSV54736648; called by muse, mutect2, varscan2
- SIPA1L2 | c.3100T>C p.C1034R | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs200800863, COSV53387718; called by muse, mutect2, varscan2
- SIVA1 | c.168C>G p.H56Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.415); catalogued as COSV57331436; called by muse, mutect2, varscan2
- SKIDA1 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as COSV71610820; called by muse, mutect2, varscan2
- SLIT3 | c.4292A>T p.Y1431F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs757342617, COSV60602057; called by muse, mutect2, varscan2
- SLITRK3 | c.1718T>A p.F573Y | Missense Mutation (SNP) | VAF 98/126 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV53846971; called by muse, varscan2
- SP4 | c.2336C>A p.T779N | Missense Mutation (SNP) | VAF 59/80 reads (74%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV56021816; called by muse, mutect2, varscan2
- SPESP1 | c.743C>A p.P248Q | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV52987067; called by muse, mutect2, varscan2
- SPHKAP | c.1951G>T p.A651S | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV60874271; called by muse, mutect2, varscan2
- SPP2 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV51445052; called by muse, mutect2, varscan2
- STK38 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57708212, COSV57709135; called by muse, mutect2, varscan2
- SV2A | c.1536C>A p.F512L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV64964504; called by muse, varscan2
- SVEP1 | c.2487G>A p.M829I | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.275); catalogued as COSV57033226, COSV57048086; called by muse, mutect2, varscan2
- SYNE1 | c.8263A>T p.K2755* (on ENST00000367255 / NM_182961.4; = p.K2762* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 43/72 reads (60%) | catalogued as COSV54948718; called by muse, mutect2, varscan2
- SYNE1 | c.4202A>C p.K1401T (on ENST00000367255 / NM_182961.4; = p.K1408T on NM_033071.3) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV54948777; called by muse, varscan2
- SYT7 | c.34G>C p.A12P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.094); catalogued as rs1273686857, COSV55654886, COSV55659411; called by muse, mutect2
- TACR2 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as COSV64822045; called by muse, mutect2, varscan2
- TBL1XR1 | c.1531G>C p.D511H | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV70500513; called by muse, mutect2, varscan2
- TCTN3 | c.1576T>A p.C526S | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV56446560; called by muse, mutect2, varscan2
- TDRD10 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV63811349; called by muse, varscan2
- TEKT4 | c.1163A>G p.Q388R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as rs782205598, COSV54624058; called by muse, mutect2, varscan2
- TMEM237 | c.743A>G p.Y248C (on ENST00000409883 / NM_001044385.3; = p.Y240C on NM_152388.4) | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs746840773, COSV53804346; called by muse, mutect2, varscan2
- TNFRSF9 | c.416G>T p.C139F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66349002; called by muse, mutect2, varscan2
- TNN | c.2729C>A p.A910D | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53424176; called by muse, mutect2, varscan2
- TNPO2 | c.118C>G p.Q40E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV63507956; called by muse, mutect2, varscan2
- TNR | c.2434G>C p.D812H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54870543, COSV54878593; called by muse, mutect2, varscan2
- TOP1MT | c.952A>G p.I318V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV61317173; called by muse, varscan2
- TP53 | c.731del p.G244Afs*3 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | catalogued as CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; called by mutect2, pindel, varscan2
- TPTE | c.476A>T p.N159I (on ENST00000618007 / NM_199261.4; = p.N141I on NM_199259.4) | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749339905; called by muse, mutect2, varscan2
- TRIM46 | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV55278539; called by muse, varscan2
- TRPM6 | c.1253G>C p.W418S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62506723; called by muse, mutect2, varscan2
- TTC21B | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as rs777506886, COSV54629263; called by muse, mutect2, varscan2
- TTN | c.49663T>C p.S16555P (on ENST00000591111; = p.S9131P on NM_003319.4) | Missense Mutation (SNP) | VAF 20/279 reads (7%) | PolyPhen possibly damaging (0.714); catalogued as COSV59974643; called by muse, mutect2
- TTN | c.10328G>A p.R3443K (on ENST00000591111; = p.R3397K on NM_003319.4) | Missense Mutation (SNP) | VAF 12/88 reads (14%) | PolyPhen benign (0); catalogued as COSV59974788; called by muse, mutect2
- UBE3B | c.2551G>T p.E851* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as COSV61073708, COSV61076233; called by muse, mutect2, varscan2
- USB1 | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV54621694; called by muse, mutect2, varscan2
- USP34 | c.586del p.A196Hfs*5 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as COSV68401399; called by mutect2, pindel, varscan2
- VWC2 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 42/90 reads (47%) | catalogued as COSV61483836, COSV61485442; called by muse, mutect2, varscan2
- WDR48 | c.1989G>C p.K663N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56531276; called by muse, mutect2, varscan2
- WNT7B | c.386G>A p.S129N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as COSV59749102; called by muse, varscan2
- WSCD2 | c.337C>G p.R113G | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.319); catalogued as COSV54580736, COSV99774458; called by muse, mutect2, varscan2
- ZFHX4 | c.8428A>G p.I2810V | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.171); catalogued as COSV50661761; called by muse, mutect2, varscan2
- ZFP37 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs1369575017, COSV65286471; called by muse, mutect2, varscan2
- ZNF208 | c.3138A>T p.E1046D | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.083); catalogued as COSV68103203; called by muse, mutect2, varscan2
- ZNF239 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs1564455066, COSV60018429; called by muse, mutect2, varscan2
- ZNF496 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.89); catalogued as COSV54175637; called by muse, mutect2, varscan2
- ZNF667 | c.1531A>T p.S511C | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV52632966; called by muse, mutect2, varscan2
- ZNF823 | c.1162C>A p.Q388K (on ENST00000341191 / NM_001297610.2; = p.Q344K on NM_017507.2) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV100362427; called by muse, mutect2, varscan2
- ZZZ3 | c.1069G>T p.V357F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.051); catalogued as COSV66232134; called by muse, mutect2, varscan2
- AREG | c.736G>T p.G246* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- CDC42BPA | c.334del p.E112Kfs*3 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- COL22A1 | c.3761del p.P1254Lfs*174 | Frame Shift Del (DEL) | VAF 63/217 reads (29%) | called by mutect2, pindel, varscan2
- IGKV6D-41 | c.330G>T p.Q110H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); called by mutect2, varscan2
- MRC1 | c.2389C>G p.P797A | Missense Mutation (SNP) | VAF 77/138 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PIK3CG | c.693G>T p.Q231H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.011); called by mutect2, varscan2
- RSPO4 | c.178_179insA p.R60Qfs*37 | Frame Shift Ins (INS) | VAF 16/35 reads (46%) | called by mutect2, varscan2
- SCARF1 | c.1867_1868insA p.A623Dfs*6 | Frame Shift Ins (INS) | VAF 12/19 reads (63%) | called by mutect2, pindel, varscan2
- SFI1 | c.1307_1308del p.E436Afs*118 (on ENST00000400288 / NM_001007467.3; = p.E405Afs*118 on NM_014775.4) | Frame Shift Del (DEL) | VAF 18/172 reads (10%) | called by pindel, varscan2
- SYCP2L | c.236_237delinsG p.F79Cfs*8 | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | called by pindel, varscan2*
- VPS8 | c.2654_2655del p.A885Gfs*7 (on ENST00000625842 / NM_001349294.1; = p.A883Gfs*7 on NM_015303.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/126 reads (10%) | called by mutect2, pindel, varscan2
- ABCA3 | c.4177C>A p.R1393= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV57051858; called by muse, mutect2, varscan2
- AHNAK2 | c.7911C>G p.A2637= | Silent (SNP) | VAF 34/244 reads (14%) | catalogued as COSV60912127; called by muse, varscan2
- AKAP4 | c.1947C>T p.C649= | Silent (SNP) | VAF 32/45 reads (71%) | catalogued as rs782396822, COSV62074119; called by mutect2, varscan2
- ALG2 | c.738C>T p.A246= | Silent (SNP) | VAF 24/153 reads (16%) | catalogued as COSV53059225; called by muse, mutect2, varscan2
- C1QTNF7 | c.18T>C p.Y6= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV54851634; called by muse, mutect2, varscan2
- C2orf66 | c.294C>G p.L98= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV61098722; called by mutect2, varscan2
- C5orf34 | c.606C>A p.I202= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV60929477; called by muse, mutect2, varscan2
- CACNA1H | c.1068C>T p.N356= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs369894677; ClinVar: likely benign; called by mutect2, varscan2
- CCNC | c.567C>T p.C189= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV58333908; called by mutect2, varscan2
- DEPTOR | c.285G>C p.R95= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as COSV53814532; called by muse, mutect2, varscan2
- DSCAML1 | c.4266G>C p.T1422= (on ENST00000321322; = p.T1362= on NM_020693.4) | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV58387234; called by muse, mutect2, varscan2
- EPHA5 | c.816C>A p.P272= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs974894393, COSV56638885; called by muse, mutect2, varscan2
- ERICH3 | c.4236G>A p.G1412= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as rs752395772, COSV58603436; called by muse, mutect2, varscan2
- FMN2 | c.4668C>A p.L1556= | Silent (SNP) | VAF 88/166 reads (53%) | catalogued as COSV60425626; called by muse, mutect2, varscan2
- FSHR | c.957G>A p.E319= | Silent (SNP) | VAF 127/252 reads (50%) | catalogued as COSV58620977; called by muse, mutect2, varscan2
- GJA10 | c.1008C>T p.S336= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV65355009; called by muse, mutect2, varscan2
- GNAT3 | c.387G>A p.R129= | Silent (SNP) | VAF 22/147 reads (15%) | catalogued as COSV68068365; called by muse, mutect2, varscan2
- GPR32 | c.513C>T p.A171= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV54514104; called by muse, mutect2, varscan2
- GTPBP4 | c.1068G>T p.V356= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV62550544; called by muse, mutect2, varscan2
- KDM4D | c.708G>C p.R236= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV58634171; called by muse, mutect2, varscan2
- L1TD1 | c.1074A>T p.L358= | Silent (SNP) | VAF 26/157 reads (17%) | catalogued as COSV63133351; called by muse, mutect2, varscan2
- LRP1B | c.6891T>A p.T2297= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV67203033; called by mutect2, varscan2
- MAP1B | c.5901C>T p.P1967= | Silent (SNP) | VAF 51/84 reads (61%) | catalogued as rs767226026, COSV57096886, COSV57097628; called by muse, varscan2
- MBD1 | c.1614G>A p.K538= (on ENST00000269468 / NM_001323950.1; = p.K436= on NM_002384.2) | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV53999755; called by muse, mutect2, varscan2
- MMRN1 | c.3075G>C p.L1025= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV53335929; called by muse, mutect2, varscan2
- MUL1 | c.753A>T p.T251= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV51641340; called by muse, mutect2, varscan2
- MYH13 | c.4482G>A p.E1494= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV52824546, COSV99353491; called by muse, mutect2, varscan2
- MYOM3 | c.1167C>A p.L389= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV58392312; called by mutect2, varscan2
- MYRIP | c.309C>G p.V103= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as COSV56886426; called by muse, mutect2, varscan2
- NCOA1 | c.2298G>C p.L766= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV56042030; called by muse, mutect2, varscan2
- NDN | c.825C>A p.I275= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs762132398, COSV59359260, COSV59361324; called by mutect2, varscan2
- NEB | c.6366C>G p.V2122= | Silent (SNP) | VAF 43/145 reads (30%) | catalogued as COSV51056896; called by muse, mutect2, varscan2
- NISCH | c.3807C>A p.L1269= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs1352598691, COSV58734344; called by muse, varscan2
- NLRP3 | c.1812G>A p.L604= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV60222194; called by muse, mutect2, varscan2
- NUP155 | c.3993G>A p.L1331= (on ENST00000231498 / NM_153485.3; = p.L1272= on NM_004298.4) | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV51528731; called by muse, mutect2, varscan2
- OR13A1 | c.9G>T p.L3= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV65572193; called by muse, mutect2, varscan2
- OR2B11 | c.642C>G p.P214= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV59509826; called by muse, mutect2, varscan2
- OR4A15 | c.393G>A p.L131= | Silent (SNP) | VAF 50/194 reads (26%) | catalogued as COSV59033843; called by muse, mutect2, varscan2
- OR56A3 | c.480T>A p.T160= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV61568806; called by muse, mutect2, varscan2
- PCDH15 | c.3750C>T p.V1250= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV57287485, COSV57371384; called by muse, mutect2, varscan2
- PCDHA6 | c.579G>A p.G193= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as COSV65350942; called by muse, mutect2, varscan2
- PDE4DIP | c.3081G>A p.L1027= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV57687782; called by muse, varscan2
- PLCXD3 | c.303C>T p.T101= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV60607250; called by muse, varscan2
- POU3F4 | c.339C>T p.A113= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV64538526; called by muse, mutect2
- RRAGA | c.162G>A p.G54= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as COSV65843102; called by muse, mutect2, varscan2
- RUNX1T1 | c.669C>A p.T223= (on ENST00000265814 / NM_001198628.1; = p.T196= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as COSV56142566, COSV99751572; called by muse, mutect2, varscan2
- SASH1 | c.228C>T p.D76= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs749204773, COSV66560639; called by muse, mutect2, varscan2
- SGO2 | c.1107T>C p.A369= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV63414703; called by muse, mutect2, varscan2
- SNX9 | c.636G>A p.A212= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs138249048, COSV101093984; called by mutect2, varscan2
- SYNE1 | c.12165C>A p.V4055= (on ENST00000367255 / NM_182961.4; = p.V3984= on NM_033071.3) | Silent (SNP) | VAF 43/64 reads (67%) | catalogued as COSV54948656; called by muse, mutect2, varscan2
- SYT14 | c.1479A>G p.L493= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs768344145, COSV55051517; called by muse, mutect2, varscan2
- TCHHL1 | c.2541T>A p.S847= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV64285386; called by muse, mutect2, varscan2
- TET3 | c.2307A>T p.S769= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV59880601; called by muse, mutect2, varscan2
- TEX33 | c.384G>A p.Q128= (on ENST00000381821 / NM_001163857.2; = p.Q43= on NM_178552.4) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV67821623; called by muse, mutect2, varscan2
- TMC2 | c.1962A>T p.P654= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV62651466; called by muse, mutect2, varscan2
- TRIM33 | c.2412T>G p.A804= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV61821737; called by muse, mutect2, varscan2
- TTC14 | c.222G>T p.L74= | Silent (SNP) | VAF 100/120 reads (83%) | catalogued as COSV56010449; called by muse, mutect2, varscan2
- TTLL5 | c.1722A>G p.P574= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs1299969424, COSV54030943; called by muse, mutect2, varscan2
- TYRO3 | c.1314G>A p.T438= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as rs369583019; called by muse, mutect2, varscan2
- USP34 | c.6357A>T p.T2119= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV68399971; called by muse, varscan2
- VSIG8 | c.495G>A p.L165= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV63652654, COSV63653562; called by mutect2, varscan2
- ZIM3 | c.54C>A p.T18= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV54141488, COSV99517792; called by mutect2, varscan2
- ZNF114 | c.459T>A p.R153= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV59943924; called by muse, mutect2, varscan2
- ZNF236 | c.4674G>T p.S1558= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV53485584; called by muse, mutect2, varscan2
- ZNF486 | c.489T>C p.F163= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs1338902458, COSV58718406; called by muse, mutect2, varscan2
- ZNF624 | c.2160A>G p.G720= | Silent (SNP) | VAF 38/64 reads (59%) | catalogued as COSV60939680; called by muse, mutect2, varscan2
- ZNF813 | c.1182G>A p.Q394= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV67175905, COSV67176183; called by muse, mutect2, varscan2
- AKR1D1 | c.690-173C>G | Intron (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99652871; called by muse, mutect2, varscan2
- BCCIP | chr10:125841318 A>G | 3'Flank (SNP) | VAF 7/41 reads (17%) | catalogued as COSV52939282; called by muse, mutect2, varscan2
- ETFB | c.58-201G>C | Intron (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100495542; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397517 A>G | 3'Flank (SNP) | VAF 18/67 reads (27%) | catalogued as rs1023645131; called by muse, mutect2, varscan2
- MIR329-1 | n.13G>T | RNA (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- NBPF7 | n.169G>A | RNA (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- OR2W5 | n.1170C>A | RNA (SNP) | VAF 36/104 reads (35%) | catalogued as rs1414929661; called by mutect2, varscan2
- REG3G | c.*1G>T | 3'UTR (SNP) | VAF 26/69 reads (38%) | catalogued as COSV99709278; called by muse, mutect2, varscan2
- RORA | c.196+51377G>C | Intron (SNP) | VAF 15/32 reads (47%) | catalogued as COSV55037446, COSV55042395; called by muse, mutect2, varscan2
- SPTBN4 | c.5915+33C>T | Intron (SNP) | VAF 17/23 reads (74%) | catalogued as COSV100150224; called by muse, mutect2, varscan2
- ZBTB37 | chr1:173866309 C>T | 5'Flank (SNP) | VAF 19/69 reads (28%) | catalogued as rs777546426; called by muse, mutect2, varscan2
- ZNF99 | c.*857C>G | 3'UTR (SNP) | VAF 10/32 reads (31%) | catalogued as COSV101233802, COSV68055371; called by muse, mutect2, varscan2
